Surgical pathology report (de-identified scan), TCGA case TCGA-3K-AAZ8, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Boston Medical Center, specimen TCGA-3K-AAZ8-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN(S) RECEIVED
SEGMENT (FIVE) V LIVER RESECTION

Pathologic Staging (pTNM):

ICD O-3
Carcinoma, hepatocellular 8170/3
Site: Liver C22.0
JN 4/30/14

[page 2 of 3]
TNM Descriptors (required only if applicable)
m (multiple primary tumors)

Primary Tumor (pT)
pT3b: Single tumor or multiple tumors of any size involving a major branch of the portal vein or hepatic veins

Regional Lymph Nodes (pN)
pNX: Cannot be assessed
No regional lymph nodes submitted or found
Number of lymph nodes examined: 0
Number of lymph nodes involved: 0

Distant Metastasis (pM)
Not applicable

Additional Pathologic Findings:

Fibrosis score: Trichrome stain shows portal and periportal fibrosis, bridging with occasional nodules (Incomplete Cirrhosis) (Ishak score 5) (F1)
Mild Steatosis
Iron stain is negative

Clinical History:
Hepatitis C infection

Comment:
AJCC PATHOLOGIC STAGE: (pT(m)3b; pNx)

THIS CASE HAS BEEN REVIEWED IN THE

Immunohistochemistry Disclaimer:

These tests were developed and their performance characteristics determined by the manufacturer. They have not been cleared or approved by the U.S. Food and Drug Administration, however, the FDA has determined that such clearance or approval is not necessary. The tests were used for clinical purposes and should not be regarded as investigative or for research.

*** Report Electronically Signed ***

CLINICAL DIAGNOSIS AND HISTORY

Hepatocellular carcinoma

FROZEN SECTION DIAGNOSIS

SEGMENTAL RESECTION OF LIVER. MULTINODULAR TUMOR MASS, 5.5 CM, 1.5CM AWAY FROM CLOSEST PARENCHYMAL MARGIN.

GROSS DESCRIPTION

The specimen is received fresh in a single container labeled with the patient's name, medical record number, and identified as "Segment V Liver Resection". The specimen consists of a segmental resection of liver measuring 12 x 7.5 x 5.5 cm and weighing 204.3 grams. The specimen has been oriented by the surgeon with one stitch marking the lateral pole. There is a discolored area on the surface measuring 6.5 x 4.0 x 3.5 cm. The resection margin has been inked black and the capsule which appears intact is inked blue. On serial sectioning a 5.5 x 4.8 x 3.5 cm, multinodular, friable, tan mass with focal hemorrhages was identified in

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

addition to multiple adjacent satellite tumor nodules measuring up to 1.5 x 1 x 1 cm. The closest parenchymal margin is 1.5 cm away. The largest tumor mass abuts the capsule. An intraoperative consult has been performed. The specimen has been submitted representatively in eight cassettes: 1- tumor and satellite lesions closest to the resection margin, 2- tumor plus capsule, 3- tumor nodules, 4- tumor with adjacent thickened capsule, 5- a perpendicular section of the lateral margin, 6- perpendicular and shaved medial margins, 7- tumor plus capsule, and 8- tumor in relation to resection margin.

Dictated by: _____

By the signature above, the senior pathologist certifies that s/he personally conducted the evaluation of the described specimen(s) and rendered the diagnosis(es) related thereto.

Source: NCI Genomic Data Commons file d1809d3d-724a-4931-be8e-a1c53f56d201 (TCGA-3K-AAZ8.61B69388-FA7E-4AE5-A3F5-104BCE12284F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).